Somatic mutation profile of tumor specimen TARGET-10-PARRJV-09A (aliquot TARGET-10-PARRJV-09A-01D) from TARGET case TARGET-10-PARRJV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (711 days).
Specimen TARGET-10-PARRJV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65cea06d-8669-4f93-9c33-b20d8d4acaff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARRJV-10A (Blood Derived Normal), aliquot TARGET-10-PARRJV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa469beb-eb35-4d84-86d7-87eb1fbf02d5

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs761085729; called by muse, mutect2, varscan2
- GRM5 | c.2497G>A p.V833M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100549600, COSV59624917; called by muse, mutect2, varscan2
- APOB | c.4137C>A p.S1379R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H2AC1 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- IGLV10-54 | chr22:22215245 del AGCATTGGACAGCAGCCTCAGTGCTCACACAGTGCCTCA | Missense Mutation (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- PRRX1 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PTPRD | c.807G>T p.W269C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SF3B2 | c.1817C>A p.P606Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXO40 | c.946C>A p.R316= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs755676833, COSV57526239; called by muse, mutect2, varscan2
